TCGA case TCGA-JX-A3Q8 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/34629eb8-0c5e-4910-8e13-bf7d6a1e337f

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 40 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, endocervical type: ICD-O-3 morphology code: 8384/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 40.6 years (14,839 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; AJCC pathologic T: T1b1; AJCC pathologic N: N0; AJCC pathologic M: MX; FIGO stage: Stage IB1; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 14; Lymphatic invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Pharmaceutical Therapy, NOS, postoperative; adjuvant Radiation Therapy, NOS; adjuvant Radiation Therapy, NOS, postoperative.

Follow-up (9 entries)
- Day 6 (postoperative): ECOG performance status: 0.
- Day 32 (preoperative): Days to imaging: 32 days; Imaging type: PET; Imaging result: Negative; Imaging anatomic site: Cervix Uteri; Imaging findings: Extra-Pelvic Metastatic Disease; Imaging suv: 7.1.
- Day 32 (preoperative): Days to imaging: 32 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 32 (preoperative): Days to imaging: 32 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 32 (preoperative): Days to imaging: 32 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 32 (preoperative): Days to imaging: 32 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 32 (preoperative): Days to imaging: 32 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 922 (postoperative): Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 1,357 days (3.7 years); Disease response: Tumor Free; ECOG performance status: 0.

Molecular and laboratory tests
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV16].
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV35].
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV33].
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV45].
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV58].
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV59].
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV39].
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV56].
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV31].
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV51].
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV18].
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV68].
- Human Papillomavirus (PCR): Positive [Hpv strain: HPV52].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Comorbidities: Human Papillomavirus Infection; Risk factors: Human Papillomavirus Infection.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Initial Diagnosis; Weight: 68 kg; Height: 158 cm; BMI: 27.2.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-JX-A3Q8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-JX-A3Q8-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-JX-A3Q8-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-JX-A3Q8-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 1; Pregnancies count miscarriage: 1; Pregnancies count induced abortion: 1; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 3; Tobacco smoking history indicator: 1; Performance status other timing: Post operative visit; Days from index date to performance status: 6; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Endocervical Type of Adenocarcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: Yes; Lymphovascular invasion: Absent; Corpus involvement: Absent; HPV types other: 31.33, 35.39, 45.51, 52.56.58.59.68; New tumor event diagnosis indicator: No.
- Fdg or ct pet performed outcomes: Fedpet or ct results: Bladder Absent; Fedpet or ct results: Extra-Pelvic Metastatic Disease Absent; Fedpet or ct results: Parametrium Absent; Fedpet or ct results: Paraaortic Nodes Absent; Fedpet or ct results: Pelvic Nodes Absent; Fedpet or ct results: Supraclavicular Absent.
- Human papillomavirus types: HPV types positive: HPV 16; HPV types positive: HPV 18; HPV types positive: Other HPV type(s).
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Performance status other timing: Post-operative follow-up; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Follow-up form 1, Treatment, Radiation therapy info: Radiation treatment reason not completed: Not done per treating physician discretion.
- Follow-up form 1, Treatment, Concurrent prescription treatment info: Chemo concurrent reason not given: Not done per treating physicians discretion.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; Performance status other timing: Follow-up visit; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,357 days; disease-specific survival: no event (censored), 1,357 days; disease-free interval: no event (censored), 1,357 days; progression-free interval: no event (censored), 1,357 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-JX-A3Q8-01A-11D-A21P-01): tumor purity 0.86, ploidy 3.12, whole-genome doublings 1.
